Somatic mutation profile of tumor specimen MP2PRT-PAVAZU-TMP1-A (aliquot MP2PRT-PAVAZU-TMP1-A-1-0-D-A820-36) from MP2PRT case MP2PRT-PAVAZU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (659 days).
Specimen MP2PRT-PAVAZU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03d2127f-8647-47fc-bbb9-cf366bbd0834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVAZU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVAZU-NB1-A-1-0-D-A820-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fe990ec4-caa6-4f07-9234-0fe82e8b88ef

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 144/484 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs397507511, CM030493, COSV61004768, COSV61009351; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LTBP1 | c.2018C>T p.S673L (on ENST00000404816 / NM_206943.4; = p.S347L on NM_000627.4) | Missense Mutation (SNP) | VAF 87/253 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as rs757007022; called by muse, mutect2, varscan2
- SLC26A11 | c.1036G>A p.G346S | Missense Mutation (SNP) | VAF 162/335 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs140725186, COSV63280903; called by muse, mutect2, varscan2
- SPOCK2 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 173/409 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368653698, COSV100436306; called by muse, mutect2, varscan2
- IGKV2-30 | chr2:89244765 del GCTGTACCACTGTGGGAGGCCAGTGT | Missense Mutation (DEL) | VAF 66/81 reads (81%) | called by mutect2, pindel, varscan2
- SEMA4B | c.1993C>A p.Q665K | Missense Mutation (SNP) | VAF 18/582 reads (3%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPATA18 | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 98/219 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRAV8-2 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 32/440 reads (7%) | called by muse, mutect2
- ABCA8 | c.1350C>T p.H450= | Silent (SNP) | VAF 16/492 reads (3%) | catalogued as rs1328985216; called by muse, mutect2
- FAT2 | c.7386A>G p.R2462= | Silent (SNP) | VAF 114/374 reads (30%) | called by muse, mutect2, varscan2
- OR10P1 | c.27G>A p.L9= | Silent (SNP) | VAF 105/259 reads (41%) | called by muse, mutect2, varscan2
